MMRF case MMRF_2464 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/04493a15-abb5-4663-ad1b-de7e22601e3a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,041 days); ISS stage: II; Days to last known disease status: 693 days (1.9 years); Days to last follow up: 693 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 49 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 120 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 210 days; Days to treatment end: 241 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 210 days; Days to treatment end: 232 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.6 mg/dL; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 28 g/L; Total Protein 11 g/dL; Glucose 6 mmol/L; C-Reactive Protein 3.61 mg/dL.
- Day 86 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.81 ×10⁹/L; Absolute Neutrophil 6.05 ×10⁹/L; Platelets 313 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 33 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 182 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.98 mg/dL; Immunoglobulin G 8.32 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 30 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 277 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.9 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.17 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 5.67 mmol/L.
- Day 350 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.32 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 5.88 ×10⁹/L; Absolute Neutrophil 4.09 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 27 g/L; Total Protein 6.6 g/dL; Glucose 5.78 mmol/L.
- Day 462: Serum Free Immunoglobulin Light Chain, Kappa 7.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.35 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.92 g/L; Lactate Dehydrogenase 6.15 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 4.91 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 26 g/L; Total Protein 6.3 g/dL; Glucose 8.64 mmol/L.
- Day 560 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 29 g/L; Total Protein 6 g/dL; Glucose 6.93 mmol/L.
- Day 616 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.17 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 693 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.56 mg/dL; Hemoglobin 6.45 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 29 g/L; Total Protein 6.3 g/dL; Glucose 6.88 mmol/L.

Other clinical attributes
- Day -3: Weight: 102 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2464_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2464_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
